Somatic mutation profile of tumor specimen 0DYKSF from CCDI case PBCSSW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 12.4 years (4,520 days).
Specimen 0DYKSF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a14cbf85-d6d3-4647-9a5c-08aeaf87d349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYKRL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97bb050f-79dd-419e-9593-c7881a23a7ba

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA4 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 188/511 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSR | c.1513A>T p.I505F | Missense Mutation (SNP) | VAF 167/463 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- INTS9 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 165/475 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- KAT2A | c.1065C>A p.H355Q | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2
- MAST4 | c.2112G>A p.M704I (on ENST00000403625 / NM_001164664.2; = p.M515I on NM_015183.3) | Missense Mutation (SNP) | VAF 178/463 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PYCR3 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 93/521 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- C15orf39 | c.585A>C p.P195= | Silent (SNP) | VAF 41/178 reads (23%) | called by muse, mutect2, varscan2
- GATA4 | c.843G>T p.L281= | Silent (SNP) | VAF 188/518 reads (36%) | catalogued as COSV58735920; called by muse, mutect2, varscan2
- GRXCR2 | c.138G>A p.K46= | Silent (SNP) | VAF 213/618 reads (34%) | catalogued as COSV65060874; called by muse, mutect2, varscan2
- ITPRID1 | c.3189A>G p.*1063= | Silent (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- LRP1 | c.6096T>A p.R2032= | Silent (SNP) | VAF 178/446 reads (40%) | called by muse, mutect2, varscan2
- TRPV4 | c.2442G>T p.V814= | Silent (SNP) | VAF 156/459 reads (34%) | called by muse, mutect2, varscan2
- TRIM67 | c.1045-12288G>A | Intron (SNP) | VAF 157/428 reads (37%) | called by muse, mutect2, varscan2
